Gene-level copy-number profile of tumor specimen TCGA-HC-8264-01B from TCGA case TCGA-HC-8264, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 60.7 years (22,177 days).
Specimen TCGA-HC-8264-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.45a0f345-3bc2-45a4-a315-8dc79eb98b11.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HC-8264-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/be3617a3-0ca5-4969-831b-6fc607dae3ce

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 40; copy number 1: 5,403; copy number 2: 52,896; copy number 3: 1,154; copy number 4: 327.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HC-8264-01B-11D-2391-01): tumor purity 0.67, ploidy 1.98, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 40 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:11,307,077–12,829,975, 40 genes (within-gene range 0–4): PRB4, PRB1, PRB2, AC078950.1, HIGD1AP8, AC007450.4, AC007450.3, DDX55P1, AC007450.2, AC007450.1, RNU7-60P, LINC01252, ETV6, BCL2L14, PTMAP9, MIR1244-4, LRP6, AC007537.1, RNU6-545P, AC007621.3, RNU6-318P, MANSC1, RPL23AP66, LOH12CR2, BORCS5, AC007619.2, DUSP16, AC007619.1, AC092824.1, CREBL2, RPL21P136, AC008115.4, GPR19, AC008115.2, CDKN1B, AC008115.3, AC008115.1, APOLD1, MIR613, STX8P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 3,022. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
